Somatic mutation profile of tumor specimen TARGET-10-PANXAM-09A (aliquot TARGET-10-PANXAM-09A-01D) from TARGET case TARGET-10-PANXAM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,741 days).
Specimen TARGET-10-PANXAM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c8770f3-e519-4a8d-a5af-d90bae326189.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANXAM-10A (Blood Derived Normal), aliquot TARGET-10-PANXAM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4002f487-d8bc-4bef-98d2-4c04f58d424b

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Frame Shift Ins 2, Silent 2, Nonsense Mutation 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ENO4 | c.623del p.K208Rfs*32 (on ENST00000622726; = p.K207Rfs*32 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs761717176; called by mutect2, varscan2
- FTMT | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs531790984; called by muse, mutect2, varscan2
- GJA1 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 48/273 reads (18%) | catalogued as rs1278599967, CM103354, COSV56997207; called by muse, mutect2, varscan2
- LTBP1 | c.2983C>T p.R995C (on ENST00000404816 / NM_206943.4; = p.R669C on NM_000627.4) | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs1319590884, COSV63188607; called by muse, mutect2, varscan2
- MFSD5 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 66/123 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs199705102, COSV61565651; called by muse, mutect2, varscan2
- NUAK1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs772183684, COSV54605730; called by muse, mutect2, varscan2
- RAB3C | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.471); catalogued as rs190927640; called by muse, mutect2, varscan2
- SH3D19 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757203859, COSV100455557; called by muse, mutect2, varscan2
- CCDC149 | c.91A>T p.S31C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GHR | c.1062T>A p.D354E | Missense Mutation (SNP) | VAF 105/240 reads (44%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- MSH5 | c.1474G>C p.D492H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPM1D | c.1382T>C p.V461A | Missense Mutation (SNP) | VAF 140/261 reads (54%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TRDV2 | chr14:22423041 ins CGAGG | Frame Shift Ins (INS) | VAF 55/66 reads (83%) | called by mutect2, pindel, varscan2
- ZCCHC17 | c.91dup p.A31Gfs*26 | Frame Shift Ins (INS) | VAF 96/237 reads (41%) | called by mutect2, pindel, varscan2
- IGLV4-69 | c.358_359insT p.*120L | Silent (INS) | VAF 45/52 reads (87%) | called by mutect2, pindel*, varscan2
- SPRR3 | c.351C>T p.V117= | Silent (SNP) | VAF 38/85 reads (45%) | called by muse, mutect2
- AGPAT5 | c.219+115C>A | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
